Somatic mutation profile of tumor specimen TCGA-AB-2935-03A (aliquot TCGA-AB-2935-03A-01W-0745-08) from TCGA case TCGA-AB-2935, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.7 years (24,349 days).
Specimen TCGA-AB-2935-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2fafa435-fc5a-4a00-896c-d799fc907ea5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2935-11A (Solid Tissue Normal), aliquot TCGA-AB-2935-11A-01W-0745-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58c8578e-5dea-40ea-bea3-5646a1e1d9c4

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Silent 2, Nonsense Mutation 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 45/103 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRL4 | c.1618A>C p.S540R | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as COSV100876367; called by muse, mutect2
- ANO3 | c.2183G>C p.G728A | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as COSV56808675, COSV99884639; called by muse, mutect2, varscan2
- ATP1A2 | c.970G>A p.G324S | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV63402212; called by muse, mutect2
- FCGBP | c.7951G>A p.E2651K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.61); catalogued as rs755987497, COSV55456112; called by muse, mutect2
- FREM2 | c.8862C>T p.D2954= | Splice Region (SNP) | VAF 19/77 reads (25%) | catalogued as COSV99750023; called by muse, mutect2, varscan2
- GJB3 | c.429C>G p.F143L | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV99055558; called by muse, mutect2, varscan2
- KCNRG | c.116A>G p.D39G | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as COSV100078497; called by muse, mutect2
- MOCOS | c.1466G>A p.R489H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.094); catalogued as rs182781411, COSV99733756; called by muse, mutect2, varscan2
- DNAH11 | c.11332G>T p.E3778* | Nonsense Mutation (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- MAOA | c.355dup p.I119Nfs*8 | Frame Shift Ins (INS) | VAF 3/27 reads (11%) | called by mutect2, pindel
- ALOX5 | c.1527C>T p.F509= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs1161630564, COSV65551058; called by muse, mutect2, varscan2
- GOLGA4 | c.645G>A p.E215= | Silent (SNP) | VAF 6/115 reads (5%) | catalogued as COSV100729076; called by muse, mutect2
